Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9J7, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9J7-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M Service: Received:
Reported:
Submitting Physician:
Pathologist:
Intraop Pathologist:
Performing Physician:

CLINICAL HISTORY:
SUBCUTANEOUS LESION ON PATIENT WITH LARGE RENAL MASS.

PREOPERATIVE DIAGNOSIS:
NA

SPECIMEN TYPE(S):
A: RIGHT ANTERIOR CHEST WALL LESION
B: RIGHT RADICAL NEPHRECTOMY
C: RIGHT PGOAS MUSCLE MASS

FINAL DIAGNOSIS:
A. RIGHT ANTERIOR CHEST WALL LESION:
Metastatic renal cell carcinoma with sarcomatoid features, see comment.

COMMENT: Immunohistochemical stains with adequate controls were performed on block labeled A1 to further investigate this case. The neoplastic cells show immunoreactivity with pancytokeratin AE1/3 and Vimentin. The S-100 show focal non specific reactivity. They are negative with TTF-1, CK-5/6, CK7, CK20, CD-10 and Pan melanoma.

B. RIGHT KIDNEY, RADICAL NEPHRECTOMY:
Papillary renal cell carcinoma, with focal sarcomatoid features, see Key
Pathological Findings.

C. RIGHT SOFT MUSCLE MASS:
Metastatic carcinoma, similar to part A.
Inked surgical margin negative for tumor.

KEY PATHOLOGICAL FINDINGS

Procedure:	Right radical nephrectomy
Tumor type:	Papillary renal cell carcinoma, with focal sarcomatoid
Features-Nuclear grade:	Grade III
Pattern of growth:	Papillary and hemorrhagic
Tumor size:	12 x 11.5 x 9 cm
Tumor location:	Superior medial aspect of the kidney
Renal capsule invasion:	The tumor penetrates into, but no beyond the renal capsule. Invasion of Gerota fascia: Not identified
Renal vein invasion:	Not present
Surgical margins:	Vascular and ureter margins negative for tumor.
Non-neoplastic kidney:	No significant pathologic changes.
Adrenal gland:	Not examined
Lymph nodes:	Not examined
Pathologic stage:	T2 NX NX Yes

I, _____, M.D. the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically Signed out by

OTHER RELATED CLINICAL DATA:
NA

ICD-O-3
Carcinoma, papillary renal cell
Site B Kidney NOS 8260/3
C64.9
W428/14

[page 2 of 2]
INTRAOPERATIVE DIAGNOSIS:
FROZEN SECTION DIAGNOSIS

PSAL. RIGHT ANTERIOR CHEST WALL LESION:
Poorly differentiated carcinoma, probably kidney.

COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by

I, M.D., have performed the intraoperative
consultation(s) and issued the above diagnoses at

GROSS DESCRIPTION:

- A. Specimen is received fresh labeled "lesion right anterior chest-wall". The specimen consists of an ovoid, moderately firm, tan-white to tan-pink nodule measuring 1.5 x 1.5 x 1.0 cm. The margin of resections are inked in black. The specimen is serially sectioned to reveal tan-white to tan-pink partially necrotic cut surface. Representative fresh tissue is submitted to Tissue Procurement Laboratory. Representative sections are submitted for frozen section evaluation as PSAL, and the remaining tissue is entirely submitted as A1-A2.
- B. Specimen is received fresh labeled "right radical nephrectomy". The specimen consists of a 604.6 gram kidney surrounded by an irregular fibroadipose tissue envelope measuring 15.0 x 14.0 x 9.5 cm in overall dimension. Prior to sectioning the specimen, the perinephric fat is inked in black. On sectioning there is an ovoid tumor mass located in the superior-medial aspect of the kidney. The tumor mass, 12.0 x 11.5 x 9.0 cm, is spherical, tan-yellow to tan-brown, and there are areas of hemorrhage and necrosis. The tumor does not invade the caliceal system and does not invade the renal sinus. The tumor does not penetrate through the renal capsule to involve the perinephric fat. The tumor is well-demarcated from the uninvolved renal parenchyma. Additional tumor nodules are not grossly identified. The medullary cord, calices and renal pelvis, are unremarkable. Attached to the kidney is a 5.0 cm length of ureter which is unremarkable. The renal artery reveals mild atherosclerotic changes and the renal vein is not grossly involved by tumor. The adrenal gland is not identified. On sectioning the hilar fat, no lymph nodes are isolated. Representative fresh tissue is submitted to Tissue Procurement Laboratory. Representative sections are submitted as follows:
- B1: Ureter, vein, and artery at margin of resection
- B2: Tumor in relation to inked perinephric fat margin of resection
- B3-B4: Tumor
- B9: Uninvolved renal parenchyma
- B10: Perihilar fibroadipose tissue.
- C. Specimen is received fresh labeled "right pectoral muscle mass". The specimen consists of an ovoid, moderately firm, dark-red-brown nodule, measuring 2.7 x 3.0 x 2.0 cm. The specimen is serially sectioned to reveal a tan-white to tan-pink partially necrotic cut surface. Representative fresh tissue is not submitted to Tissue Procurement Laboratory. Representative sections are submitted as C1-C2.

hw 1/3/14

Source: NCI Genomic Data Commons file 5c3a6cb5-1636-4994-9843-2424f56b6af3 (TCGA-2Z-A9J7.069BFE2C-691F-4D48-BA0D-554678931C59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).